Somatic mutation profile of cancer-model specimen HCM-BROD-0445-C15-85M (3D Organoid, passage 5; aliquot HCM-BROD-0445-C15-85M-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0445-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 56.0 years (20,467 days).
Specimen HCM-BROD-0445-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3887817-f940-468d-ac54-809a4ca9c774.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0445-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0445-C15-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74f1f237-6e1c-408a-8527-3c2747ac8c7a

The open-access MAF lists 205 somatic variants for this specimen: 150 protein-altering or splice-affecting, 46 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 46, Nonsense Mutation 10, Frame Shift Ins 4, Frame Shift Del 4, 3'UTR 3, Intron 3, Splice Site 2, 5'Flank 1, In Frame Del 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.387C>A p.Y129* | Nonsense Mutation (SNP) | VAF 325/639 reads (51%) | hotspot (GDC flag); catalogued as COSV58684005, COSV58689871; called by muse, mutect2, varscan2
- LMNA | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 212/804 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs786205448; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 429/429 reads (100%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AARD | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 536/695 reads (77%) | SIFT tolerated (0.58); PolyPhen benign (0.082); catalogued as COSV100991891; called by muse, mutect2, varscan2
- AC004593.2 | c.1482C>A p.D494E | Missense Mutation (SNP) | VAF 62/877 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56088072, COSV56099974; called by muse, mutect2
- ADAMTS2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 192/422 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs767850400, COSV99201369; called by muse, mutect2
- ADAMTS5 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 555/738 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs766100243, COSV53182969; called by muse, mutect2, varscan2
- APOBEC4 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 158/697 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as rs867527033, COSV58017983; called by muse, mutect2, varscan2
- ART5 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 41/484 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV51706409; called by muse, mutect2
- BHMT2 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758118459; called by muse, mutect2, varscan2
- BTBD8 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1216746678; called by muse, mutect2, varscan2
- C12orf50 | c.1116C>A p.N372K | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1352366753; called by muse, mutect2, varscan2
- CACNB2 | c.1269G>C p.M423I (on ENST00000324631 / NM_201596.3; = p.M368I on NM_000724.4) | Missense Mutation (SNP) | VAF 298/298 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.175); catalogued as rs552801377, COSV56647290; called by muse, mutect2, varscan2
- CD38 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 74/166 reads (45%) | catalogued as rs772659735; called by muse, mutect2, varscan2
- CDH18 | c.2057A>G p.K686R | Missense Mutation (SNP) | VAF 289/390 reads (74%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV56960342; called by muse, mutect2, varscan2
- CHD7 | c.3802G>A p.E1268K | Missense Mutation (SNP) | VAF 105/477 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as CM109233; called by muse, mutect2, varscan2
- CHRM3 | c.1011G>T p.W337C | Missense Mutation (SNP) | VAF 233/507 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV55085773; called by muse, mutect2, varscan2
- CHST14 | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 286/644 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs754720949; called by muse, mutect2, varscan2
- CNTN6 | c.947-1del p.X316_splice | Splice Site (DEL) | VAF 15/123 reads (12%) | catalogued as COSV100611534; called by mutect2, pindel, varscan2
- CPNE8 | c.1243T>G p.F415V | Missense Mutation (SNP) | VAF 106/162 reads (65%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as COSV100503720, COSV58850235; called by muse, mutect2, varscan2
- CSMD2 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 136/283 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745628955, COSV104384893; called by muse, varscan2
- CSMD3 | c.9842G>A p.G3281D (on ENST00000297405 / NM_001363185.1; = p.G3112D on NM_052900.3) | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333652160; called by muse, mutect2
- DISP3 | c.2887G>A p.D963N | Missense Mutation (SNP) | VAF 135/407 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs775462722, COSV53819266; called by muse, mutect2, varscan2
- FAM155A | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 171/328 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs866313554, COSV65558130, COSV65582864; called by muse, mutect2, varscan2
- FAM181B | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 180/879 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.565); catalogued as COSV61300878; called by muse, mutect2, varscan2
- FBXO10 | c.1621G>C p.G541R | Missense Mutation (SNP) | VAF 21/383 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99446626; called by muse, mutect2
- FGD1 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 260/260 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs771102505, COSV100911299; called by muse, mutect2, varscan2
- FLG | c.4615A>G p.S1539G | Missense Mutation (SNP) | VAF 118/534 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100912077, COSV64237938; called by muse, mutect2
- GAGE1 | c.279T>G p.D93E | Missense Mutation (SNP) | VAF 34/605 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67747837; called by muse, mutect2
- GKAP1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.487); catalogued as rs779955656, COSV64489186; called by muse, mutect2, varscan2
- GNPAT | c.1698A>C p.L566F | Missense Mutation (SNP) | VAF 81/355 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100791591; called by muse, mutect2, varscan2
- GSG1L | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 157/302 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs1272229676; called by muse, mutect2, varscan2
- HGF | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 264/360 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776090604, COSV55945716; called by muse, mutect2, varscan2
- HIVEP3 | c.7216G>A p.A2406T | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs768355978; called by muse, mutect2, varscan2
- IQSEC3 | c.2545G>A p.V849I (on ENST00000538872 / NM_001170738.2; = p.V546I on NM_015232.1) | Missense Mutation (SNP) | VAF 113/233 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs782450946; called by muse, mutect2, varscan2
- KCNB2 | c.141A>C p.E47D | Missense Mutation (SNP) | VAF 425/553 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101579045, COSV73049565; called by muse, mutect2, varscan2
- KCNJ5 | c.1027T>A p.F343I | Missense Mutation (SNP) | VAF 64/445 reads (14%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as COSV100610699; called by muse, mutect2, varscan2
- KHDRBS2 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55490301; called by muse, mutect2, varscan2
- LOXL4 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 113/346 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs544139451, COSV53257655; called by muse, mutect2, varscan2
- MAP2K2 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 197/416 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs370799450, COSV53568067; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MGA | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs1272090898; called by muse, mutect2, varscan2
- MIDN | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 177/427 reads (41%) | catalogued as COSV56295993; called by muse, mutect2, varscan2
- MUC19 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs940274264; called by muse, mutect2, varscan2
- MYLK3 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 116/335 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs376487384; called by muse, mutect2, varscan2
- MYOG | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 359/748 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as rs752485385, COSV54095108; called by muse, varscan2
- NAV2 | c.2788C>T p.R930W (on ENST00000396087 / NM_001244963.2; = p.R907W on NM_145117.5) | Missense Mutation (SNP) | VAF 222/379 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs775581508, COSV62335933; called by muse, mutect2, varscan2
- NLGN1 | c.571T>G p.L191V | Missense Mutation (SNP) | VAF 213/436 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100848722; called by muse, mutect2, varscan2
- NLRC3 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 243/493 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs372379793; called by muse, mutect2, varscan2
- NPR1 | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 197/430 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs368538785; called by muse, mutect2, varscan2
- NTNG2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 348/549 reads (63%) | SIFT tolerated (1); PolyPhen possibly damaging (0.454); catalogued as rs757167158; called by muse, mutect2, varscan2
- OR2AJ1 | c.815A>C p.K272T | Missense Mutation (SNP) | VAF 107/463 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100561459; called by muse, mutect2, varscan2
- OR51Q1 | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.642); catalogued as COSV56178359; called by muse, mutect2, varscan2
- OR56A4 | c.797T>A p.L266H | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100417521; called by muse, mutect2, varscan2
- OR8J2 | c.293C>A p.A98E | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs777271290; called by muse, mutect2
- PKD1L1 | c.6748C>T p.R2250* | Nonsense Mutation (SNP) | VAF 435/436 reads (100%) | catalogued as rs200518403, COSV56971699, COSV99221710; called by muse, mutect2, varscan2
- PLXDC2 | c.511T>C p.F171L | Missense Mutation (SNP) | VAF 402/402 reads (100%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV65904751; called by muse, mutect2, varscan2
- PTPRM | c.3290C>G p.A1097G | Missense Mutation (SNP) | VAF 93/214 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100159613, COSV59845639; called by muse, mutect2, varscan2
- RREB1 | c.4333C>T p.P1445S | Missense Mutation (SNP) | VAF 18/682 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as rs1233706327, COSV58560368; called by muse, mutect2
- SALL3 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 44/44 reads (100%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1362215791; called by muse, mutect2, varscan2
- SERTAD2 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 108/420 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs201663885; called by muse, mutect2, varscan2
- SIRPB1 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 38/760 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.048); catalogued as rs747745133, COSV53540647; called by muse, mutect2
- SLITRK5 | c.1510G>T p.V504F | Missense Mutation (SNP) | VAF 136/372 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV61522487; called by muse, mutect2, varscan2
- SOX1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 99/195 reads (51%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.874); catalogued as rs1398178334; called by muse, mutect2, varscan2
- TOB2 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 214/432 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs568919168; called by muse, mutect2, varscan2
- TOP3B | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 186/395 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs201487411, COSV64117987; called by muse, mutect2, varscan2
- TRDN | c.1043A>G p.E348G | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs755708624, COSV100520474, COSV62115434; called by muse, mutect2, varscan2
- UBQLN3 | c.1685G>C p.R562T | Missense Mutation (SNP) | VAF 192/337 reads (57%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.879); catalogued as COSV100293367; called by muse, mutect2, varscan2
- UBR3 | c.4741G>A p.E1581K | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.019); catalogued as rs749222366; called by muse, mutect2, varscan2
- ULK1 | c.3088G>A p.V1030I | Missense Mutation (SNP) | VAF 170/567 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs143671996; called by muse, mutect2, varscan2
- UNK | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 119/283 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1431006082; called by muse, mutect2, varscan2
- YIPF7 | c.82T>G p.L28V | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV60657676; called by muse, mutect2, varscan2
- ZNF410 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 94/193 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs957898281; called by muse, mutect2, varscan2
- ZNF638 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 26/359 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776893707, COSV52498766; called by muse, mutect2
- ZNF835 | c.1415A>C p.K472T | Missense Mutation (SNP) | VAF 131/590 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101606367; called by muse, mutect2, varscan2
- ZP1 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 303/470 reads (64%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs759784256, COSV53923376; called by muse, mutect2, varscan2
- AC013489.1 | c.184T>A p.L62M | Missense Mutation (SNP) | VAF 277/277 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- AKR1B15 | c.814del p.T272Pfs*6 | Frame Shift Del (DEL) | VAF 85/351 reads (24%) | called by mutect2, pindel, varscan2
- ALS2 | c.1060G>T p.D354Y | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ANK2 | c.3183C>A p.S1061R | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- APOB | c.10651G>T p.A3551S | Missense Mutation (SNP) | VAF 131/455 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- APOB | c.3560A>C p.K1187T | Missense Mutation (SNP) | VAF 213/304 reads (70%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- AREL1 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ASTN1 | c.2969T>C p.L990P | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2
- BCLAF3 | c.2102dup p.K702Efs*13 (on ENST00000379682 / NM_001367774.1; = p.K673Efs*13 on NM_198279.3) | Frame Shift Ins (INS) | VAF 60/83 reads (72%) | called by mutect2, pindel, varscan2
- C4BPA | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 76/393 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMSAP1 | c.3822+1G>A p.X1274_splice | Splice Site (SNP) | VAF 68/275 reads (25%) | called by muse, mutect2, varscan2
- CCDC148 | c.1318C>G p.L440V | Missense Mutation (SNP) | VAF 16/507 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CFAP65 | c.4489G>T p.E1497* | Nonsense Mutation (SNP) | VAF 23/615 reads (4%) | called by muse, mutect2
- CITED2 | c.787C>G p.Q263E | Missense Mutation (SNP) | VAF 269/396 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CLK3 | c.1272G>C p.E424D (on ENST00000395066 / NM_001130028.1; = p.E276D on NM_003992.4) | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL24A1 | c.211T>G p.L71V | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- COMP | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 328/676 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND2B | c.506C>G p.S169* | Nonsense Mutation (SNP) | VAF 219/561 reads (39%) | called by muse, mutect2, varscan2
- DSP | c.7370A>T p.Q2457L | Missense Mutation (SNP) | VAF 74/309 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ERC1 | c.2211A>G p.I737M (on ENST00000360905 / NM_178040.4; = p.I709M on NM_178039.4) | Missense Mutation (SNP) | VAF 239/384 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EYS | c.3664T>G p.L1222V | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FARP1 | c.2753G>A p.R918H | Missense Mutation (SNP) | VAF 152/665 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FMN2 | c.4096C>G p.Q1366E | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- FN3KRP | c.5A>T p.E2V | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GATA4 | c.1272G>T p.Q424H | Missense Mutation (SNP) | VAF 188/188 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GCNT4 | c.423A>C p.K141N | Missense Mutation (SNP) | VAF 126/256 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GPC4 | c.1354G>T p.V452F | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GRIK2 | c.2561dup p.R855Efs*5 | Frame Shift Ins (INS) | VAF 44/188 reads (23%) | called by mutect2, pindel, varscan2
- HOMER3 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IL10RA | c.1253G>A p.G418D | Missense Mutation (SNP) | VAF 34/1176 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- ITGBL1 | c.809A>T p.E270V | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- JARID2 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 67/260 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- KCTD9 | c.417C>A p.D139E | Missense Mutation (SNP) | VAF 84/84 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LAMA5 | c.3129C>T p.N1043= | Splice Region (SNP) | VAF 113/737 reads (15%) | called by muse, mutect2, varscan2
- LILRA6 | c.194G>T p.S65I | Missense Mutation (SNP) | VAF 631/863 reads (73%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRRC32 | c.767T>C p.L256P | Missense Mutation (SNP) | VAF 190/896 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MAGEB3 | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAK | c.1069C>A p.Q357K | Missense Mutation (SNP) | VAF 110/414 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MSL1 | c.39_40insAAGGCC p.A13_P14insKA | In Frame Ins (INS) | VAF 130/1193 reads (11%) | called by mutect2, pindel, varscan2
- NALCN | c.4271T>G p.L1424R | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NBPF10 | c.283T>C p.Y95H | Missense Mutation (SNP) | VAF 157/157 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- NGFR | c.1228C>G p.R410G | Missense Mutation (SNP) | VAF 497/710 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPAS3 | c.2118dup p.L707Afs*146 (on ENST00000356141 / NM_001164749.2; = p.L675Afs*146 on NM_022123.3) | Frame Shift Ins (INS) | VAF 126/332 reads (38%) | called by pindel, varscan2
- NRG3 | c.2115A>T p.Q705H (on ENST00000404547 / NM_001370084.1; = p.Q681H on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 179/179 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- NXPE4 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 135/1106 reads (12%) | called by muse, mutect2, varscan2
- OR4A16 | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 210/311 reads (68%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- OR8K5 | c.588A>T p.E196D | Missense Mutation (SNP) | VAF 74/236 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- PCDH8 | c.2615G>A p.R872H | Missense Mutation (SNP) | VAF 123/524 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- PCDHB7 | c.2170T>C p.S724P | Missense Mutation (SNP) | VAF 178/367 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PGAP1 | c.1735G>T p.V579F | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2
- POMGNT1 | c.940T>G p.Y314D | Missense Mutation (SNP) | VAF 85/190 reads (45%) | PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PRR14L | c.5785C>T p.P1929S | Missense Mutation (SNP) | VAF 170/258 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRR36 | c.3787C>G p.R1263G | Missense Mutation (SNP) | VAF 391/783 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- RAG2 | c.1426T>C p.Y476H | Missense Mutation (SNP) | VAF 15/464 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- RBMXL3 | c.1522G>A p.G508S | Missense Mutation (SNP) | VAF 347/349 reads (99%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- RICTOR | c.5070_5072del p.E1690_A1691delinsD | In Frame Del (DEL) | VAF 185/284 reads (65%) | called by mutect2, pindel, varscan2
- RNF31 | c.779_780insACTGG p.V261Lfs*9 | Frame Shift Ins (INS) | VAF 103/260 reads (40%) | called by mutect2, pindel, varscan2
- SAR1B | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SCAF1 | c.3121C>A p.Q1041K | Missense Mutation (SNP) | VAF 148/738 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.647); called by muse, varscan2
- SF1 | c.905C>G p.S302* | Nonsense Mutation (SNP) | VAF 94/340 reads (28%) | called by muse, mutect2, varscan2
- SLC6A2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 197/495 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TAS2R19 | c.854del p.K285Sfs*2 | Frame Shift Del (DEL) | VAF 241/524 reads (46%) | called by mutect2, pindel, varscan2
- TCOF1 | c.3928C>T p.Q1310* (on ENST00000377797 / NM_001135243.1; = p.Q1233* on NM_000356.4) | Nonsense Mutation (SNP) | VAF 115/266 reads (43%) | called by muse, varscan2
- TENM4 | c.4070A>G p.K1357R | Missense Mutation (SNP) | VAF 100/518 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TG | c.482C>A p.P161Q | Missense Mutation (SNP) | VAF 285/364 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLN1 | c.7284del p.K2429Sfs*3 | Frame Shift Del (DEL) | VAF 171/430 reads (40%) | called by mutect2, pindel, varscan2
- TMC6 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 210/427 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TMEM132C | c.2135G>A p.S712N | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- TTN | c.47858C>A p.A15953D (on ENST00000591111; = p.A8529D on NM_003319.4) | Missense Mutation (SNP) | VAF 104/435 reads (24%) | PolyPhen possibly damaging (0.564); called by muse, varscan2
- TXNRD3 | c.19C>G p.Q7E | Missense Mutation (SNP) | VAF 395/395 reads (100%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- VENTX | c.409del p.T137Pfs*8 | Frame Shift Del (DEL) | VAF 77/259 reads (30%) | called by mutect2, pindel, varscan2
- WIZ | c.4148G>A p.G1383D (on ENST00000673675 / NM_001371589.1; = p.G288D on NM_021241.3) | Missense Mutation (SNP) | VAF 176/376 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- WNK2 | c.3968C>G p.A1323G | Missense Mutation (SNP) | VAF 124/600 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- WNT8A | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 117/322 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZFR2 | c.2491G>A p.G831R | Missense Mutation (SNP) | VAF 197/474 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCA12 | c.7392T>C p.N2464= (on ENST00000272895 / NM_173076.3; = p.N2146= on NM_015657.3) | Silent (SNP) | VAF 79/308 reads (26%) | called by muse, mutect2, varscan2
- AMDHD1 | c.567C>T p.C189= | Silent (SNP) | VAF 231/334 reads (69%) | catalogued as rs755356880, COSV57140455; called by muse, mutect2, varscan2
- CACNA1F | c.3093C>T p.D1031= | Silent (SNP) | VAF 194/194 reads (100%) | catalogued as rs782655905, COSV59903014; called by muse, mutect2, varscan2
- CAPN11 | c.1191C>T p.G397= | Silent (SNP) | VAF 297/464 reads (64%) | called by muse, mutect2, varscan2
- CAPN3 | c.1962C>T p.F654= | Silent (SNP) | VAF 94/267 reads (35%) | catalogued as rs770394924; called by muse, mutect2, varscan2
- CARD11 | c.1956G>A p.S652= | Silent (SNP) | VAF 277/772 reads (36%) | catalogued as rs987289095, COSV62755261; called by muse, mutect2, varscan2
- CSMD3 | c.558A>G p.K186= | Silent (SNP) | VAF 104/456 reads (23%) | catalogued as rs1321339317; called by muse, mutect2, varscan2
- DHX8 | c.3504C>T p.I1168= | Silent (SNP) | VAF 121/390 reads (31%) | catalogued as rs1210054837; called by muse, mutect2, varscan2
- ELF1 | c.1701G>A p.Q567= | Silent (SNP) | VAF 109/496 reads (22%) | called by muse, mutect2, varscan2
- FCHO2 | c.21C>G p.V7= | Silent (SNP) | VAF 54/420 reads (13%) | catalogued as COSV99821747; called by muse, mutect2, varscan2
- FOXE1 | c.912G>A p.A304= | Silent (SNP) | VAF 231/727 reads (32%) | catalogued as rs761084888; called by muse, mutect2, varscan2
- GRM2 | c.1275C>T p.N425= | Silent (SNP) | VAF 105/197 reads (53%) | catalogued as rs752525900; called by muse, mutect2, varscan2
- H3C13 | c.270G>A p.V90= | Silent (SNP) | VAF 163/926 reads (18%) | called by muse, mutect2, varscan2
- HNRNPA0 | c.213C>G p.A71= | Silent (SNP) | VAF 182/489 reads (37%) | called by muse, mutect2, varscan2
- HTR3A | c.1042C>T p.L348= | Silent (SNP) | VAF 427/770 reads (55%) | catalogued as COSV55468833; called by muse, mutect2, varscan2
- JPH2 | c.1821C>T p.P607= | Silent (SNP) | VAF 204/983 reads (21%) | catalogued as rs949299046; called by muse, mutect2, varscan2
- KCNT1 | c.570C>T p.R190= (on ENST00000488444; = p.R209= on NM_020822.3) | Silent (SNP) | VAF 139/453 reads (31%) | catalogued as rs1417508265, COSV99706251; called by muse, mutect2, varscan2
- MRPS18A | c.474C>T p.S158= | Silent (SNP) | VAF 82/447 reads (18%) | catalogued as rs775971977, COSV64521820; called by muse, mutect2, varscan2
- NOTCH1 | c.687C>T p.N229= | Silent (SNP) | VAF 86/1044 reads (8%) | catalogued as rs535217359; ClinVar: likely benign; called by muse, mutect2
- NRG3 | c.1641A>G p.R547= (on ENST00000404547 / NM_001370084.1; = p.R326= on NM_001165973.1) | Silent (SNP) | VAF 171/171 reads (100%) | called by muse, mutect2, varscan2
- NRXN3 | c.3051C>A p.G1017= (on ENST00000335750 / NM_001330195.2; = p.G644= on NM_004796.6) | Silent (SNP) | VAF 228/229 reads (100%) | called by muse, mutect2, varscan2
- NYAP2 | c.1005G>A p.P335= | Silent (SNP) | VAF 104/482 reads (22%) | catalogued as rs1474403566, COSV56011117; called by muse, mutect2, varscan2
- OAF | c.87G>A p.P29= | Silent (SNP) | VAF 286/1462 reads (20%) | catalogued as rs1182000432; called by muse, mutect2, varscan2
- OR52I2 | c.912A>G p.Q304= | Silent (SNP) | VAF 160/431 reads (37%) | catalogued as COSV57044069, COSV57044562; called by muse, mutect2, varscan2
- OR5T3 | c.837T>G p.A279= | Silent (SNP) | VAF 250/351 reads (71%) | catalogued as rs781773301, COSV57381322; called by muse, mutect2, varscan2
- PCDHA8 | c.1038C>T p.N346= | Silent (SNP) | VAF 91/231 reads (39%) | catalogued as rs1157712945, COSV65336144; called by muse, mutect2, varscan2
- PCDHB12 | c.2334C>T p.S778= | Silent (SNP) | VAF 109/238 reads (46%) | catalogued as rs782599976; called by muse, mutect2, varscan2
- PRB4 | c.120C>G p.R40= | Silent (SNP) | VAF 173/318 reads (54%) | called by muse, mutect2, varscan2
- PRKG1 | c.57C>T p.I19= | Silent (SNP) | VAF 229/230 reads (100%) | called by muse, mutect2, varscan2
- PTPRT | c.783C>T p.S261= | Silent (SNP) | VAF 282/638 reads (44%) | catalogued as rs374941317, COSV62006627; called by muse, varscan2
- RPS15 | c.141G>A p.R47= | Silent (SNP) | VAF 219/801 reads (27%) | catalogued as rs886789572, COSV51831404; called by muse, mutect2, varscan2
- SEPHS1 | c.276C>T p.I92= | Silent (SNP) | VAF 187/441 reads (42%) | catalogued as rs774883874, COSV59260472; called by muse, mutect2, varscan2
- SETBP1 | c.744C>T p.T248= | Silent (SNP) | VAF 88/161 reads (55%) | catalogued as COSV56314251; called by muse, mutect2, varscan2
- SIGLEC7 | c.798C>T p.V266= | Silent (SNP) | VAF 201/297 reads (68%) | called by muse, mutect2, varscan2
- SLC10A3 | c.1248G>A p.T416= | Silent (SNP) | VAF 630/632 reads (100%) | catalogued as rs781794691; called by muse, mutect2, varscan2
- SLIT2 | c.2778G>A p.P926= | Silent (SNP) | VAF 167/169 reads (99%) | catalogued as rs374788306; called by muse, mutect2, varscan2
- SNX20 | c.594C>T p.A198= | Silent (SNP) | VAF 237/506 reads (47%) | catalogued as rs1363705317, COSV56057718; called by muse, mutect2, varscan2
- STARD3NL | c.72T>C p.N24= | Silent (SNP) | VAF 232/590 reads (39%) | called by muse, mutect2, varscan2
- SVOP | c.1434C>T p.I478= | Silent (SNP) | VAF 103/511 reads (20%) | catalogued as rs768122599, COSV54464988; called by muse, mutect2, varscan2
- TCF25 | c.837C>T p.L279= | Silent (SNP) | VAF 60/187 reads (32%) | catalogued as rs999796438; called by muse, mutect2, varscan2
- TPRG1 | c.192G>A p.R64= | Silent (SNP) | VAF 38/494 reads (8%) | called by muse, mutect2
- TUBG2 | c.462G>T p.L154= | Silent (SNP) | VAF 26/763 reads (3%) | called by muse, mutect2
- WHAMM | c.1629A>G p.R543= | Silent (SNP) | VAF 164/164 reads (100%) | called by muse, mutect2, varscan2
- XPR1 | c.717A>G p.L239= | Silent (SNP) | VAF 104/393 reads (26%) | called by muse, mutect2, varscan2
- ZNF385D | c.1047G>T p.V349= | Silent (SNP) | VAF 238/238 reads (100%) | catalogued as COSV99874942; called by muse, mutect2, varscan2
- ZNF585B | c.1965T>G p.T655= | Silent (SNP) | VAF 385/411 reads (94%) | called by muse, mutect2, varscan2
- GCK | c.46-5652G>A | Intron (SNP) | VAF 564/1104 reads (51%) | catalogued as rs763550503; called by muse, mutect2, varscan2
- LENG9 | c.-60A>T | 5'UTR (SNP) | VAF 11/262 reads (4%) | catalogued as rs1044403568; called by muse, mutect2
- LHX6 | c.*54C>T | 3'UTR (SNP) | VAF 161/522 reads (31%) | catalogued as rs750075092, COSV61344367; called by muse, mutect2, varscan2
- MTCL1 | chr18:8831710 C>T | 3'Flank (SNP) | VAF 145/479 reads (30%) | catalogued as rs1227085654; called by muse, mutect2, varscan2
- OR2T2 | chr1:248441592 G>A | 5'Flank (SNP) | VAF 276/662 reads (42%) | catalogued as rs759043664; called by muse, varscan2
- PRSS40A | n.142-2177G>C | Intron (SNP) | VAF 52/1118 reads (5%) | called by muse, mutect2
- RFLNB | c.*277G>A | 3'UTR (SNP) | VAF 123/439 reads (28%) | called by muse, mutect2, varscan2
- SMG7 | c.*1089C>T | 3'UTR (SNP) | VAF 134/626 reads (21%) | catalogued as COSV61631202; called by muse, mutect2, varscan2
- TTN | c.10360+2919A>T | Intron (SNP) | VAF 373/478 reads (78%) | catalogued as COSV60360756; called by muse, mutect2, varscan2
